Somatic mutation profile of tumor specimen MBCProject_0814_T1_WES (aliquot MBCProject_0814_T1_WES_1) from CMI case MBCProject_0814, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Tissue or organ of origin: Breast, NOS.
Specimen MBCProject_0814_T1_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Axilla; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c2f684be-742f-440e-b2f2-cbd9fe599ab7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_0814_SALIVA (Saliva), aliquot MBCProject_0814_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a7800229-f9b1-4993-83d5-ff44b950f536

The open-access MAF lists 27 somatic variants for this specimen: 19 protein-altering or splice-affecting, 3 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, 3'UTR 4, Silent 3, Nonsense Mutation 2, Frame Shift Del 1, Splice Site 1, Frame Shift Ins 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 16/47 reads (34%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ARHGEF40 | c.2819G>A p.R940H | Missense Mutation (SNP) | VAF 14/103 reads (14%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as rs1260057829, COSV53881875; called by muse, mutect2, varscan2
- C8orf74 | c.569G>T p.R190L | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.69); PolyPhen benign (0.005); catalogued as rs192663026; called by mutect2, varscan2
- CACNA1C | c.178C>T p.R60W | Missense Mutation (SNP) | VAF 32/114 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.936); catalogued as COSV100223511; called by muse, mutect2, varscan2
- DELE1 | c.1462G>A p.G488R | Missense Mutation (SNP) | VAF 44/147 reads (30%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.018); catalogued as rs776537398, COSV99191884; called by muse, mutect2, varscan2
- MAP2K4 | c.319G>T p.E107* | Nonsense Mutation (SNP) | VAF 14/53 reads (26%) | catalogued as COSV62255448; called by muse, mutect2, varscan2
- MYL10 | c.78+2T>C p.X26_splice | Splice Site (SNP) | VAF 6/50 reads (12%) | catalogued as rs1364564511, COSV56208945; called by muse, mutect2
- PCDHA2 | c.103G>A p.V35I | Missense Mutation (SNP) | VAF 22/220 reads (10%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.08); catalogued as COSV65369662; called by muse, mutect2
- TTN | c.31640del p.K10547Rfs*17 (on ENST00000591111; = p.K9620Rfs*17 on NM_133378.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 3/18 reads (17%) | catalogued as COSV60124124; called by pindel, varscan2
- ATP12A | c.931G>T p.A311S | Missense Mutation (SNP) | VAF 34/86 reads (40%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ATXN2L | c.855C>A p.N285K | Missense Mutation (SNP) | VAF 12/116 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by mutect2, varscan2
- DARS2 | c.56G>A p.R19K | Missense Mutation (SNP) | VAF 29/97 reads (30%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- GPR162 | c.287C>T p.T96I | Missense Mutation (SNP) | VAF 16/142 reads (11%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- HERC1 | c.6952dup p.R2318Kfs*34 | Frame Shift Ins (INS) | VAF 16/108 reads (15%) | called by mutect2, pindel, varscan2
- KLHL34 | c.1455A>C p.R485S | Missense Mutation (SNP) | VAF 15/105 reads (14%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, mutect2, varscan2
- MAVS | c.1555C>T p.Q519* | Nonsense Mutation (SNP) | VAF 6/50 reads (12%) | called by mutect2, varscan2
- MOB3A | c.188T>G p.V63G | Missense Mutation (SNP) | VAF 26/110 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- SIGLEC10 | c.2060C>A p.T687N | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.209); called by muse, mutect2, varscan2
- ZNF287 | c.529G>T p.V177L | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.607); called by muse, mutect2, varscan2
- EPHA10 | c.765C>T p.H255= | Silent (SNP) | VAF 12/112 reads (11%) | catalogued as rs774606674; called by mutect2, varscan2
- EXOSC6 | c.345C>T p.G115= | Silent (SNP) | VAF 18/26 reads (69%) | catalogued as rs1179156800; called by muse, varscan2
- LAMC2 | c.3270C>T p.N1090= | Silent (SNP) | VAF 7/42 reads (17%) | catalogued as rs574584189, COSV51453393; called by mutect2, varscan2
- CLRN1 | c.*552A>G | 3'UTR (SNP) | VAF 4/14 reads (29%) | catalogued as rs751972163; called by mutect2, varscan2
- DNAJC19 | c.*690A>G | 3'UTR (SNP) | VAF 4/28 reads (14%) | catalogued as rs1370714837, COSV104423365; called by muse, varscan2
- SLC25A23 | c.483+452A>G | Intron (SNP) | VAF 4/24 reads (17%) | catalogued as rs764806788; called by mutect2, varscan2
- UPF2 | c.*228A>G | 3'UTR (SNP) | VAF 10/76 reads (13%) | called by muse, mutect2, varscan2
- VAPB | c.*153_*156del | 3'UTR (DEL) | VAF 2/32 reads (6%) | catalogued as rs1405425035; called by muse*, mutect2
